Gene-level copy-number profile of specimen HCM-CSHL-0800-C67-85A from HCMI case HCM-CSHL-0800-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; Tumor grade: G3.
Specimen HCM-CSHL-0800-C67-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 3.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3cd56174-97ce-4d2e-b012-1d002741de45.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0800-C67-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,725 have no estimate.
https://portal.gdc.cancer.gov/files/28cdad08-cdd7-4857-80e6-9aa158db3789

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 519; copy number 1: 1,434; copy number 2: 19,272; copy number 3: 22,416; copy number 4: 13,211; copy number 5: 1,288; copy number 6: 733; copy number 7: 16; copy number 9: 3; copy number 10: 6.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–2): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr5:62,776,877–63,023,489, 2 genes: ISCA1P1, AC113420.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 25 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,784,376–143,797,108, 3 genes, copy number 9: AC239800.3, LINC02591, RNU1-143P.
- chr5:43,336,164–43,348,716, 1 gene, copy number 7: AC114947.1.
- chr5:44,066,624–45,895,970, 15 genes, copy number 7: RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr16:8,962,706–9,156,881, 6 genes, copy number 10 (within-gene range 2–10): AC022167.3, AC087190.2, C16orf72, AC087190.3, AC087190.1, RPL21P119.

Autosomal genes at a single copy (total copy number 1): 321. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
